CPTAC case C3L-00807 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5fd1d0d8-1717-425e-9f76-805fa536806a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1961; Vital status: Dead; Days to death: 260 days; Year of death: 2019; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Hematopoietic system, NOS; Age at diagnosis: 57.7 years (21,058 days); Year of diagnosis: 2018; Days to last known disease status: 260 days; Progression or recurrence: no; Days to last follow up: 260 days.

Follow-up (1 entry)
- Days to follow up: 260 days; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 114.1 kg; Height: 160 cm; BMI: 44.57; Diabetes treatment type: Insulin.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (5 samples)
- Samples C3L-00807-50, C3L-00807-51, C3L-00807-52 (3 with the same recorded description): Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Samples C3L-00807-54, C3L-00807-55 (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: -1 day; Time between excision and freezing: 269 minutes; Method of sample procurement: Blood Draw; Diagnosis pathologically confirmed: Yes.
